Somatic mutation profile of tumor specimen MMRF_2820_1_BM_CD138pos (aliquot MMRF_2820_1_BM_CD138pos_T1_KHS5U_L15706) from MMRF case MMRF_2820, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2820_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d1f701-27d9-4184-a129-3025ae75ad01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2820_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2820_1_PB_WBC_C3_KHS5U_L15752; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b4bc551-9936-450b-85c5-d6b1337525f1

The open-access MAF lists 68 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 11, Silent 10, Intron 7, 5'UTR 6, 3'Flank 4, 5'Flank 3, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 124/263 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs984975545, COSV51125252; called by muse, varscan2
- AGTPBP1 | c.701-1G>A p.X234_splice | Splice Site (SNP) | VAF 10/264 reads (4%) | catalogued as COSV100430252; called by muse, mutect2
- CNDP1 | c.830T>A p.V277D | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62595618; called by muse, mutect2, varscan2
- CPA1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs141886698; called by muse, mutect2, varscan2
- EYA4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs747223436, COSV100765189; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FAM149A | c.1979C>T p.P660L (on ENST00000356371 / NM_001367768.2; = p.P369L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs141878617, COSV57027566; called by muse, mutect2, varscan2
- IGHV2-70 | c.76T>G p.S26A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374458740; called by muse, varscan2
- OR8K5 | c.163T>G p.L55V | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57889470; called by muse, mutect2
- PPP1R3C | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs752149540; called by muse, mutect2
- TEX55 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1281743903; called by muse, mutect2, varscan2
- TMEM131L | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as rs530138329, COSV53645110; called by muse, mutect2, varscan2
- ABAT | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EDIL3 | c.1240A>T p.N414Y | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- IGHJ1 | c.40A>C p.T14P | Missense Mutation (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2
- IGHV2-70D | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITGA2 | c.2475T>A p.F825L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- KLHL7 | c.1723G>A p.D575N (on ENST00000339077 / NM_001031710.3; = p.D527N on NM_018846.5) | Missense Mutation (SNP) | VAF 131/276 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NOMO3 | c.1172T>G p.I391S | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- NTM | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2
- OBSL1 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PLEKHM2 | c.628A>G p.S210G | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNF151 | c.365T>A p.V122E | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- UPF2 | c.3360G>C p.M1120I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ZEB2 | c.1602T>A p.N534K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRINP2 | c.201C>T p.R67= | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as rs138435872; called by muse, mutect2, varscan2
- CELSR1 | c.6855C>T p.A2285= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as rs770140686, COSV53084124, COSV99420499; called by muse, mutect2, varscan2
- FER1L6 | c.2907C>T p.P969= | Silent (SNP) | VAF 76/150 reads (51%) | catalogued as rs765886026; called by muse, mutect2, varscan2
- IGHD6-19 | c.3G>A p.G1= | Silent (SNP) | VAF 81/108 reads (75%) | catalogued as rs376893371; called by muse, varscan2
- IGLV1-40 | c.327C>T p.C109= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs769159676; called by mutect2, varscan2
- MAGEB6B | c.105A>G p.Q35= | Silent (SNP) | VAF 59/76 reads (78%) | called by muse, mutect2, varscan2
- MTMR1 | c.1143A>C p.R381= | Silent (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- NPAP1 | c.1011G>A p.P337= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as rs142610787, COSV61505934; called by muse, mutect2
- PUS3 | c.96G>A p.Q32= | Silent (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- TECRL | c.39G>A p.K13= | Silent (SNP) | VAF 101/247 reads (41%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62072262 T>G | 3'Flank (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- ARMCX5 | c.*233C>T | 3'UTR (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99863389; called by muse, mutect2, varscan2
- ATRX | c.5566+176T>G | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96088579 C>T | 3'Flank (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- C4orf50 | c.*2103G>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- CCDC153 | c.256+122C>T | Intron (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2
- DISP2 | c.-56G>A | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs368392302; called by muse, varscan2
- DZIP3 | c.*6+316C>G | Intron (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- FAM87A | n.2093C>A | RNA (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- GPATCH8 | c.-27C>T | 5'UTR (SNP) | VAF 44/85 reads (52%) | catalogued as rs769108588; called by muse, mutect2, varscan2
- HID1 | c.*794A>G | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- HID1 | c.217-43C>T | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- HMGB1 | c.-14-224T>G | Intron (SNP) | VAF 37/41 reads (90%) | called by muse, mutect2, varscan2
- IGIP | c.-1491A>T | 5'UTR (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- IGIP | c.-1490A>G | 5'UTR (SNP) | VAF 39/133 reads (29%) | called by muse, mutect2, varscan2
- IGLL5 | c.-132T>C | 5'UTR (SNP) | VAF 31/83 reads (37%) | catalogued as COSV104440300; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44569357 G>A | 3'Flank (SNP) | VAF 55/106 reads (52%) | catalogued as rs745815113; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851270 T>C | 5'Flank (SNP) | VAF 90/213 reads (42%) | catalogued as rs185157784; called by muse, varscan2
- MIR5195 | chr14:106851395 C>T | 5'Flank (SNP) | VAF 68/158 reads (43%) | catalogued as rs1310072724; called by muse, varscan2
- MOB3B | c.*2G>A | 3'UTR (SNP) | VAF 55/199 reads (28%) | called by muse, mutect2, varscan2
- NPAT | c.*1420A>G | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- OTX2 | c.*991C>T | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- PIK3CD | c.*683G>A | 3'UTR (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- SEL1L3 | chr4:25863459 T>C | 5'Flank (SNP) | VAF 105/263 reads (40%) | catalogued as rs1273572254; called by muse, varscan2
- SLC12A3 | c.*153A>G | 3'UTR (SNP) | VAF 59/107 reads (55%) | called by muse, mutect2, varscan2
- TBL3 | c.-2A>G | 5'UTR (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- TM9SF3 | c.*636A>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | catalogued as rs1264169770; called by muse, mutect2, varscan2
- TMEM47 | c.*469C>G | 3'UTR (SNP) | VAF 40/50 reads (80%) | called by muse, mutect2, varscan2
- TTC39C | c.985-805G>T | Intron (SNP) | VAF 58/224 reads (26%) | called by muse, varscan2
- VAPA | c.*5441T>G | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, varscan2
- YIPF6 | c.57+24A>G | Intron (SNP) | VAF 4/102 reads (4%) | called by muse, mutect2
- ZNF268 | chr12:133205975 A>G | 3'Flank (SNP) | VAF 31/66 reads (47%) | catalogued as rs1379725547; called by muse, mutect2, varscan2
